MMRF case MMRF_1787 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c3f1f36d-b86b-479c-8a1c-1f973f95c4fa

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.9 years (25,884 days); ISS stage: II; Days to last known disease status: 1,069 days (2.9 years); Days to last follow up: 1,069 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 82 days; Days to treatment end: 82 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 106 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 107 days; Days to treatment end: 107 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 0): M Protein 3.99 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.122 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.9 mg/dL; Immunoglobulin G 1.78 g/L; Immunoglobulin A 53.6 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.55 µg/mL; Lactate Dehydrogenase 1.35 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 8.7 g/dL; Glucose 8.53 mmol/L.
- Day 82 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.106 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.604 mg/dL; Immunoglobulin G 2.53 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 2.31 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 5.6 g/dL; Glucose 5.78 mmol/L.
- Day 155 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.365 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 4.12 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 5.3 g/dL; Glucose 6.49 mmol/L.
- Day 285 (ECOG 1): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.788 mg/dL; Immunoglobulin G 4.84 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 5.3 g/dL; Glucose 6 mmol/L.
- Day 379 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.456 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.902 mg/dL; Immunoglobulin G 6.16 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 9.67 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 5.5 mmol/L.
- Day 470 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.525 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.988 mg/dL; Immunoglobulin G 4.91 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 5.4 g/dL; Glucose 8.31 mmol/L.
- Day 603 (ECOG 2): Hemoglobin 9.61 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 160 ×10⁹/L.
- Day 698 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.934 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 6.8 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 9.55 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 6.22 mmol/L.
- Day 792 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.762 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 6.38 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.5 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 6.99 mmol/L.
- Day 887 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.901 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 6.16 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 8.86 mmol/L.
- Day 985 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.797 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.948 mg/dL; Immunoglobulin G 5.95 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 9.8 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 5.23 mmol/L.
- Day 1,069 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.883 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 6.32 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 5.9 g/dL; Glucose 7.1 mmol/L.

Other clinical attributes
- Day -17: Weight: 100 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1787_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_1787_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
